Surgical pathology report (de-identified scan), TCGA case TCGA-NF-A4WU, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-NF-A4WU-01A (Primary Tumor).

[page 1 of 3]
ICD-6-3
Carcinosarcoma NOS
8980/3

Site Path Endometrium, C54.1
C60.9 Uterus NOS, C55.9
7/2/19/13

SLIDE DISPOSITION:

DIAGNOSIS:

A. Lymph nodes, right para-aortic, below the inferior mesenteric artery, biopsy: Multiple (4) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

B. Lymph nodes, right para-aortic, above the inferior mesenteric artery, biopsy: Multiple (9) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

C. Lymph nodes, left para-aortic, below the inferior mesenteric artery, biopsy: Multiple (3) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

D. Lymph nodes, left para-aortic, above the inferior mesenteric artery, biopsy: Multiple (5) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

E. Lymph nodes, right pelvic, dissection: Multiple (15) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

F. Lymph nodes, left pelvic, biopsy: Multiple (9) lymph nodes are negative for tumor. Frozen section histologic interpretation performed by:

G. Uterus, left and right fallopian tubes and ovaries, hysterectomy and bilateral salpingo-oophorectomy: Carcinosarcoma (95% glandular, 5% homologous stromal differentiation) is identified forming a polypoid mass (3.5 x 3.3 x 2.2 cm). The glandular component comprises predominantly of a serous component with a minor endometrioid component. The tumor is confined to the endometrium. The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. Multiple (2) intramural leiomyomata (ranging in size from 0.9 cm to 1.4 cm in greatest dimension).

H-Q. Staging biopsies [bladder peritoneum, right pelvic sidewall, left pelvic sidewall, cul-de-sac, small bowel mesentery, small bowel serosa, large bowel mesentery, large bowel serosa, epiploic tag, and anterior abdominal wall] biopsies: Negative for tumor, all specimens.

R. Omentum, omentectomy: Negative for tumor.

With available surgical material [AJCC pT1aN0] (7th edition, ;

ADDENDUM:

This note is added to the final pathology report to clarify that it was based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review would be reflected in a revised report.

[page 2 of 3]
GROSS DESCRIPTION:

- A. Received fresh labeled "right para-aortic lymph nodes below the inferior mesenteric artery" is a 4.9 x 3.5 x 1.7 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted
- B. Received fresh labeled "right para-aortic lymph nodes above the inferior mesenteric artery" is a 4.8 x 2.4 x 1.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted
- C. Received fresh labeled "left para-aortic lymph nodes below the inferior mesenteric artery" is a 4.5 x 3.2 x 1.7 cm aggregate of adipose and lymphatic tissue. Multiple (3) lymph nodes submitted.
- D. Received fresh labeled "left para-aortic lymph nodes above the inferior mesenteric artery" is a 4.5 x 3.2 x 1.7 cm aggregate of adipose and lymphatic tissue. All submitted.
- E. Received fresh labeled "right pelvic lymph nodes" is a 11.4 x 7.5 x 1.7 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- F. Received fresh labeled "left pelvic lymph nodes" is a 7.4 x 4.3 x 2.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- G. Received fresh labeled "uterus, left and right fallopian tubes and ovaries" is a 115.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa has focal fibrous adhesions. There is a 3.5 x 3.3 x 2.2 cm polypoid mass in the anterior wall of the endometrial cavity without invasion, grossly. The myometrial thickness is 1.4 cm. There are multiple (2) uterine intramural leiomyomas, ranging in size from 0.9 cm to 1.4 cm. There is a 2.1 x 1.3 x 1.1 cm right ovary with a smooth outer surface and a solid cut surface with a 4.7 x 1.0 cm right fallopian tube, status posterior tubal ligation. There is a 1.7 x 1.2 x 1.1 cm left ovary with a smooth outer surface and a solid cut surface with a 4.5 x 1.1 cm left fallopian tube, status posterior tubal ligation. Representative sections are submitted.
- H. Received fresh labeled "bladder peritoneum" is a 2.2 x 1.1 x 0.4 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- I. Received fresh labeled "right pelvic sidewall" is a 2.3 x 0.7 x 0.4 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- J. Received fresh labeled "left pelvic sidewall" is a 1.8 x 0.7 x 0.5 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- K. Received fresh labeled "cul-de-sac" is a 0.8 x 0.4 x 0.3 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- L. Received fresh labeled "small bowel mesentery" is a 0.7 x 0.6 x 0.3 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- M. Received fresh labeled "small bowel serosa" is a 0.3 x 0.2 x 0.2 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- N. Received fresh labeled "large bowel mesentery" is a 0.5 x 0.3 x 0.2 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.
- O. Received fresh labeled "large bowel serosa" is a 0.3 x 0.2 x 0.2 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.

[page 3 of 3]
P. Received fresh labeled "epipolic tag" is a 1.0 x 0.6 x 0.5 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.

Q. Received fresh labeled "anterior abdominal wall" is a 1.1 x 0.6 x 0.4 cm aggregate of pink-tan to yellow soft tissue, which is entirely submitted.

R. Received fresh labeled "omentum" is an 18.0 x 12.0 x 4.0 cm portion of omentum. No masses are identified grossly. Lymph nodes are not identified. Representative sections are submitted.

Noted		☒

Source: NCI Genomic Data Commons file c198c5d5-14eb-43a0-83ca-f6cc71754e31 (TCGA-NF-A4WU.0B833955-38C7-4312-9502-D80829E30F7B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).